Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A28V, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A28V-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid cancer.

PROCEDURE: Thyroidectomy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

1CD-0-3

Carcinoma, papillary, follicular
variant

8340/3

Site: thyroid

C73.9

hr
5/25/11**FINAL DIAGNOSIS:**

PART 1: THYROID, TOTAL THYROIDECTOMY (51 MG) -

Collection Date:

- A. PAPILLARY THYROID CARCINOMA, BILATERAL, TWO FOCI (4.5 CM AND 0.4 CM)
B. LARGEST FOCUS: RIGHT LOBE, ENCAPSULATED FOLLICULAR VARIANT.
C. ALL FOCI CONFINED TO THYROID, NO CAPSULAR OR ANGIOLYMPHATIC INVASION.
D. PATHOLOGIC STAGE: pT3 N0

PART 2: PARATHYROID, LEFT SUPERIOR, PARATHYROIDECTOMY (73 MG) -
SLIGHTLY ENLARGED BUT NORMOCELLULAR PARATHYROID**CASE SYNOPSIS:****SYNOPTIC DATA - PRIMARY THYROID TUMORS****SPECIMEN TYPE:**

Total Thyroidectomy

TUMOR SITE:

Right Lobe, Left Lobe ?

TUMOR FOCALITY:

Multifocal

TUMOR SIZE (largest nodule):

Greatest Dimension: 4.5 cm

HISTOLOGIC TYPE:**

Papillary carcinoma, encapsulated follicular variant

TNM DESCRIPTORS:

m

PRIMARY TUMOR (pT):

pT3

REGIONAL LYMPH NODES (pN):

pN0

Number of regional lymph nodes examined: 0

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM):

Not applicable

EXTRATHYROIDAL EXTENSION:

Not identified

MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Not identified

Case is "circle":	☒	DISQUALIFIED

hr 5/25/11

Source: NCI Genomic Data Commons file 1957151b-b635-4440-8876-5b3801aa7f29 (TCGA-BJ-A28V.8CE75929-8C0F-4ED0-847C-DC3A442147F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).